Gene-level copy-number profile of tumor specimen TCGA-55-7907-01A from TCGA case TCGA-55-7907, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.2 years (28,201 days).
Specimen TCGA-55-7907-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.4afab294-ab5d-4e38-9ab4-b36dcce688eb.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-7907-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b506ed49-19f0-4fe7-a56e-cd4a67bd94a0

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,993; copy number 2: 11,198; copy number 3: 18,799; copy number 4: 18,657; copy number 5: 4,384; copy number 6: 2,780; copy number 7: 1,692; copy number 8: 212; copy number 9: 95; copy number 10: 5; copy number 13: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-7907-01A-11D-2166-01): tumor purity 0.39, ploidy 3.56, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,009 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:194,188,967–201,584,367, 97 genes, copy number 8–13 (broad region; genes not listed).
- chr1:244,653,103–245,134,090, 16 genes, copy number 8: DESI2, AL451007.1, AL451007.3, AL451007.2, BX323046.2, COX20, HNRNPU, BX323046.1, RN7SKP55, RNU6-947P, AL356512.1, EFCAB2, RNU6-1089P, RNU6-999P, AL589763.1, RNU1-132P.
- chr1:245,206,444–245,234,501, 1 gene, copy number 8: KIF26B-AS1.
- chr2:96,248,514–98,608,515, 68 genes, copy number 8 (broad region; genes not listed).
- chr2:119,223,831–121,649,476, 40 genes, copy number 8–10 (within-gene range 5–10): STEAP3, STEAP3-AS1, C2orf76, DBI, TMEM37, SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15, PTPN4, RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC.
- chr3:86,125,216–86,496,996, 5 genes, copy number 7: AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070.
- chr3:88,601,061–90,261,708, 11 genes, copy number 7: NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr7:51,849,086–52,503,434, 4 genes, copy number 7: AC006478.2, AC079763.1, AC006320.1, AC006459.1.
- chr8:56,917,084–68,819,023, 170 genes, copy number 7–9 (within-gene range 6–9) (broad region; genes not listed).
- chr8:69,667,046–145,066,685, 1,187 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr10:35,008,551–36,626,138, 28 genes, copy number 9: CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA.
- chr17:21,428,263–21,574,517, 1 gene, copy number 7 (within-gene range 6–7): LINC02693.
- chr17:21,504,558–29,567,037, 188 genes, copy number 7 (broad region; genes not listed).
- chr17:29,566,052–29,573,157, 2 genes, copy number 7: TP53I13, AC104564.3.
- chr17:62,626,031–66,894,751, 132 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr19:36,528,318–38,208,369, 59 genes, copy number 9 (within-gene range 6–9): AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567, ZNF850, AC020928.1, AC020928.2, ZNF790-AS1, ZNF790, ZNF345, Y_RNA, ZNF829, RPL31P61, ZNF568, ZNF420, AC010632.3, AC010632.1, AC010632.2, AC012309.1, ZNF585A, AC012309.2, ZNF585B, ZNF383, AC016590.1, LINC01535, AC016590.4, ZNF875, AC016590.3, AC016590.2, ZNF527, AC008806.1, ZNF569, ZNF570, ZNF793-AS1, AC022148.2, ZNF793, AC022148.1, ZNF571-AS1, ZNF540, ZNF571, ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87, SIPA1L3, AC008395.1, AC011465.1.

Autosomal genes at a single copy (total copy number 1): 1,186. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
